Gene-level copy-number profile of tumor specimen TCGA-TQ-A7RW-01A from TCGA case TCGA-TQ-A7RW, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 32.3 years (11,804 days).
Specimen TCGA-TQ-A7RW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.2d99f015-44d5-4446-ba72-e6f93e12d899.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TQ-A7RW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5d724344-48c9-4391-b7fe-e46fc37d4146

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 9,213; copy number 2: 48,199; copy number 3: 1,982; copy number 4: 226; copy number 5: 183.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TQ-A7RW-01A-11D-A33S-01): tumor purity 0.67, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:79,970,813–80,247,514, 10 genes (within-gene range 0–2): TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 183 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:6,148,484–6,365,885, 1 gene, copy number 5 (within-gene range 4–5): AC026167.1.
- chr3:6,490,460–11,953,085, 107 genes, copy number 5 (broad region; genes not listed).
- chr3:27,712,910–28,538,122, 8 genes, copy number 5: LINC02084, EOMES, LINC01980, LINC01981, LINC01967, CMC1, AZI2, ZCWPW2.
- chr3:28,427,963–28,448,073, 2 genes, copy number 5: FAM96AP1, AC093142.1.
- chr3:29,926,811–33,869,707, 64 genes, copy number 5 (broad region; genes not listed).
- chr3:34,152,979–34,157,297, 1 gene, copy number 5: AC123023.2.

Autosomal genes at a single copy (total copy number 1): 7,172. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
